Somatic mutation profile of cancer-model specimen HCM-BROD-0689-C71-85R (3D Neurosphere, passage 5; aliquot HCM-BROD-0689-C71-85R-01D-A83U-36), derived from the recurrence tumor of HCMI case HCM-BROD-0689-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.1 years (23,030 days).
Specimen HCM-BROD-0689-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5b8817a-bb2d-4007-8cbd-c9558e6077be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0689-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0689-C71-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/292f4fcd-6347-49b0-aefc-9401799c84ba

The open-access MAF lists 62 somatic variants for this specimen: 47 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 14, Frame Shift Del 6, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 159/160 reads (99%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs786204859, CD110173, CM983501, COSV64288670, COSV64294671; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 327/327 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BDH1 | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 185/684 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs773056463; called by muse, mutect2, varscan2
- CCNDBP1 | c.735del p.A246Rfs*3 | Frame Shift Del (DEL) | VAF 167/533 reads (31%) | catalogued as COSV55746601; called by mutect2, pindel, varscan2
- GRM1 | c.1238T>C p.V413A | Missense Mutation (SNP) | VAF 156/309 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51372504; called by muse, mutect2, varscan2
- LYPD2 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 442/854 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs1160940176; called by muse, varscan2
- LYPD6B | c.19G>C p.D7H (on ENST00000409029 / NM_001317004.1; = p.D31H on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/316 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.134); catalogued as COSV54520521; called by muse, mutect2, varscan2
- MAOB | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 143/315 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.66); catalogued as COSV65204342; called by muse, mutect2, varscan2
- NAV3 | c.5024G>T p.S1675I | Missense Mutation (SNP) | VAF 117/239 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV99888867; called by muse, mutect2, varscan2
- PRAMEF8 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 483/1007 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as rs1367743735; called by muse, mutect2, varscan2
- PRKDC | c.10127G>A p.G3376D | Missense Mutation (SNP) | VAF 301/687 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.244); catalogued as rs1272452350; called by muse, mutect2, varscan2
- PSMD10 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 318/732 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1362416960; called by muse, mutect2, varscan2
- RABGAP1 | c.2107C>T p.Q703* | Nonsense Mutation (SNP) | VAF 127/291 reads (44%) | catalogued as COSV101017032; called by muse, mutect2, varscan2
- RFC3 | c.1027T>A p.Y343N | Missense Mutation (SNP) | VAF 154/349 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66296590; called by muse, mutect2, varscan2
- SLC7A14 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 323/551 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs756436577, COSV51578448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBXT | c.626A>C p.K209T | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV51616339; called by muse, mutect2, varscan2
- TNFRSF11B | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 336/705 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs774691067; called by muse, mutect2, varscan2
- TRPC5 | c.2168del p.R723Nfs*6 | Frame Shift Del (DEL) | VAF 50/240 reads (21%) | catalogued as COSV53283720; called by mutect2, varscan2
- UGT1A1 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 183/362 reads (51%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs370790922; called by muse, varscan2
- BCHE | c.1334T>A p.F445Y | Missense Mutation (SNP) | VAF 170/573 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- COL5A1 | c.4396C>G p.P1466A | Missense Mutation (SNP) | VAF 13/406 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CPSF3 | c.29A>G p.D10G | Missense Mutation (SNP) | VAF 188/426 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- EYS | c.2567T>C p.L856P | Missense Mutation (SNP) | VAF 215/461 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HDAC3 | c.203A>G p.D68G | Missense Mutation (SNP) | VAF 179/432 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- INTS1 | c.1566G>T p.E522D | Missense Mutation (SNP) | VAF 173/432 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- IP6K3 | c.67_77del p.H23Gfs*9 | Frame Shift Del (DEL) | VAF 186/473 reads (39%) | called by mutect2, pindel, varscan2
- MYF5 | c.217A>G p.K73E | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NECTIN2 | c.236A>C p.H79P | Missense Mutation (SNP) | VAF 367/707 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NKAPL | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 155/346 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR10J1 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 116/286 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51G2 | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 63/435 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- OR56A1 | c.449T>C p.F150S | Missense Mutation (SNP) | VAF 130/288 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPFIBP2 | c.2429A>C p.K810T | Missense Mutation (SNP) | VAF 115/240 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RPS6KA1 | c.686T>C p.M229T | Missense Mutation (SNP) | VAF 180/473 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- SFSWAP | c.2675T>C p.V892A | Missense Mutation (SNP) | VAF 327/698 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SLCO5A1 | c.1720G>A p.G574R | Missense Mutation (SNP) | VAF 165/777 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SNX18 | c.1494T>A p.D498E | Missense Mutation (SNP) | VAF 232/533 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SPAG1 | c.718C>G p.P240A | Missense Mutation (SNP) | VAF 67/360 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ST6GALNAC4 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 388/408 reads (95%) | PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMPPE | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 248/525 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPC5 | c.2167del p.R723Dfs*6 | Frame Shift Del (DEL) | VAF 63/353 reads (18%) | called by mutect2*, pindel, varscan2*
- TTLL2 | c.1343A>G p.D448G | Missense Mutation (SNP) | VAF 152/398 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2
- TTPA | c.139_150delinsT p.L47Ffs*25 | Frame Shift Del (DEL) | VAF 240/1343 reads (18%) | called by pindel, varscan2*
- UBR3 | c.3338A>G p.D1113G | Missense Mutation (SNP) | VAF 102/230 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- UGT2B4 | c.551G>T p.S184I | Missense Mutation (SNP) | VAF 119/295 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- USP47 | c.2418del p.F806Lfs*58 (on ENST00000399455 / NM_001372095.1; = p.F718Lfs*58 on NM_017944.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 137/353 reads (39%) | called by mutect2, pindel, varscan2
- ZFAND4 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CNTN6 | c.495C>T p.Y165= | Silent (SNP) | VAF 126/261 reads (48%) | catalogued as rs114806249; called by muse, mutect2, varscan2
- FAM170B | c.201G>A p.G67= | Silent (SNP) | VAF 205/475 reads (43%) | catalogued as rs1327006521, COSV61254054; called by muse, varscan2
- FASTKD1 | c.87T>C p.F29= | Silent (SNP) | VAF 147/320 reads (46%) | called by muse, mutect2, varscan2
- FLNC | c.2838T>C p.Y946= | Silent (SNP) | VAF 166/350 reads (47%) | catalogued as rs769390195; called by muse, mutect2, varscan2
- IP6K1 | c.756A>G p.T252= | Silent (SNP) | VAF 169/463 reads (37%) | catalogued as rs1339097613; called by muse, mutect2, varscan2
- ITGA5 | c.1056T>C p.D352= | Silent (SNP) | VAF 214/453 reads (47%) | called by muse, mutect2, varscan2
- OR5F1 | c.330C>T p.T110= | Silent (SNP) | VAF 200/383 reads (52%) | catalogued as rs573086848, COSV53545530, COSV99558547; called by muse, mutect2
- PRRT4 | c.1626G>T p.P542= | Silent (SNP) | VAF 491/954 reads (51%) | catalogued as rs745375588; called by muse, mutect2, varscan2
- RGS12 | c.810G>A p.S270= | Silent (SNP) | VAF 253/530 reads (48%) | catalogued as rs138890505; called by muse, mutect2, varscan2
- RNF139 | c.861T>C p.S287= | Silent (SNP) | VAF 112/551 reads (20%) | catalogued as rs561882673; called by muse, mutect2, varscan2
- TRAPPC8 | c.1848G>A p.Q616= | Silent (SNP) | VAF 86/274 reads (31%) | catalogued as rs140670473; called by muse, mutect2, varscan2
- TRAV26-1 | c.162A>G p.R54= | Silent (SNP) | VAF 128/293 reads (44%) | called by muse, mutect2, varscan2
- UGT2B17 | c.996C>A p.I332= | Silent (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2, varscan2
- ZNF74 | c.1467G>C p.V489= | Silent (SNP) | VAF 256/577 reads (44%) | called by muse, mutect2, varscan2
- CXorf56 | c.243-1006G>T | Intron (SNP) | VAF 158/390 reads (41%) | catalogued as COSV100233397; called by muse, mutect2, varscan2
